Somatic mutation profile of tumor specimen 0DIY6F from CCDI case PBBWDR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.8 years (7,615 days).
Specimen 0DIY6F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f87fe5c-8d62-4614-b24f-5460aff2bb79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY5Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01d459f0-0bb4-4f93-8447-bf09dc2a5044

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLVS1 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 82/912 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.048); catalogued as rs759006982; called by muse, mutect2
- FGFR4 | c.2043G>C p.E681D | Missense Mutation (SNP) | VAF 27/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52800270, COSV52800882; called by muse, mutect2
- USP37 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 20/656 reads (3%) | catalogued as COSV51442072; called by muse, mutect2
- LGI3 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 186/459 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NOTCH3 | c.6260C>T p.A2087V | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SFTPB | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 235/816 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
